Gene-level copy-number profile of tumor specimen TCGA-GU-A766-01A from TCGA case TCGA-GU-A766, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 62.4 years (22,774 days).
Specimen TCGA-GU-A766-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.f4fccb16-01c4-481b-ba4f-51d4a1ea2e94.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-GU-A766-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a38e0626-ce0e-4804-ad59-7c6a07ec8176

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 17; copy number 1: 11,549; copy number 2: 44,421; copy number 3: 1,603; copy number 4: 1,537; copy number 5: 574; copy number 6: 119.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-GU-A766-01A-11D-A32A-01): tumor purity 0.39, ploidy 1.96, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 10 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:42,362,983–42,808,112, 5 genes: AL442163.1, AL450442.1, AL442163.2, AL442163.3, YWHAQP1.
- chr20:14,757,563–15,022,958, 5 genes: RPS10P2, MACROD2-AS1, AL138808.1, RNU6-1159P, RNU6-115P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 693 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:13,144,000–45,895,970, 462 genes, copy number 5–6 (broad region; genes not listed).
- chr10:2,071,845–2,502,200, 9 genes, copy number 6: AL441943.1, MIR6072, RNU6-889P, AL441943.2, LINC02662, RNU6-576P, LINC00701, LINC02645, AL713851.2.
- chr10:15,513,954–16,071,809, 4 genes, copy number 6: ITGA8, MINDY3, AL358033.1, FTLP19.
- chr16:12,614,451–13,779,760, 13 genes, copy number 5: AC010333.3, CPPED1, MIR4718, AC109597.1, AC109597.2, AC092324.1, RPL35AP34, SHISA9, AC009134.1, U91319.1, AC003009.1, TMF1P1, U95743.1.
- chr18:8,913,999–15,330,282, 205 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 9,135. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
